Somatic mutation profile of tumor specimen MP2PRT-PAVHMV-TMP1-A (aliquot MP2PRT-PAVHMV-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVHMV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,355 days).
Specimen MP2PRT-PAVHMV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 614e4d3e-95b2-4d23-85e4-3d6996f4f2e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHMV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHMV-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f76af141-3763-4dc2-8c6e-f8fc4bda9e71

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 63/196 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 106/424 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, varscan2
- ABCA13 | c.9485G>A p.R3162Q | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369327461; called by muse, mutect2, varscan2
- GRID1 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753413551, COSV100025114, COSV60031971; called by muse, mutect2, varscan2
- MXD4 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs776946148; called by muse, mutect2, varscan2
- PCDH19 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs368674741; called by muse, mutect2
- TRHR | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs769021256; called by muse, mutect2, varscan2
- UNC80 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs763702668, COSV55894736; called by muse, mutect2, varscan2
- VEGFC | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.328); catalogued as COSV54605885; called by muse, mutect2, varscan2
- VWDE | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as rs1479460177; called by muse, mutect2, varscan2
- ANKRD30B | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- CTCF | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 14/351 reads (4%) | called by muse, mutect2
- RBMXL3 | c.2704G>T p.G902C | Missense Mutation (SNP) | VAF 173/704 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- RP1L1 | c.2654G>T p.G885V | Missense Mutation (SNP) | VAF 165/404 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SYK | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ESX1 | c.264G>A p.E88= | Silent (SNP) | VAF 167/668 reads (25%) | catalogued as rs200053829, COSV101006506; called by muse, mutect2, varscan2
- GRIN2D | c.2499C>T p.I833= | Silent (SNP) | VAF 15/340 reads (4%) | catalogued as COSV99474373; called by muse, mutect2
- JPH4 | c.903C>T p.N301= | Silent (SNP) | VAF 162/601 reads (27%) | catalogued as COSV100689035, COSV62509374; called by muse, mutect2, varscan2
- LTBP1 | c.4998C>T p.C1666= (on ENST00000404816 / NM_206943.4; = p.C1340= on NM_000627.4) | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as rs1165073566, COSV55378693; called by muse, mutect2, varscan2
- RBFOX1 | c.978C>T p.A326= | Silent (SNP) | VAF 91/253 reads (36%) | catalogued as rs146803665, COSV100301782; called by muse, varscan2
